Somatic mutation profile of tumor specimen C3N-01168-02 (aliquot CPT0094030009) from CPTAC case C3N-01168, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.7 years (22,172 days).
Specimen C3N-01168-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f172febe-401f-408f-85ce-6139e2370c5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01168-31 (Blood Derived Normal), aliquot CPT0094070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09b00de5-b12e-421d-b825-5814a088b8e2

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, 5'UTR 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 23/220 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.131dup p.Y44* | Nonsense Mutation (INS) | VAF 24/266 reads (9%) | catalogued as rs730881673; called by mutect2, pindel
- CHRNB2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1440128191; called by muse, mutect2
- CNR1 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.122); catalogued as COSV62986734; called by muse, mutect2
- DGKZ | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs577494020; called by muse, mutect2
- ECE2 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs942717079; called by muse, mutect2, varscan2
- FAM9A | c.922T>A p.L308I | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV66813715; called by muse, mutect2
- GABRG2 | c.1461C>G p.I487M (on ENST00000361925 / NM_001375343.1; = p.I447M on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100729623; called by muse, mutect2
- GRK1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs200986774; called by muse, mutect2, varscan2
- KLHL34 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.186); catalogued as rs1426361828; called by muse, mutect2
- LILRB1 | c.1003G>T p.G335C (on ENST00000427581; = p.G299C on NM_006669.6) | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207220; called by muse, mutect2, varscan2
- MAGEA12 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 64/672 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1292630607, COSV63295359; called by muse, mutect2
- MYT1L | c.2555G>A p.R852K | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as COSV101221039, COSV67720367; called by muse, varscan2
- OBSCN | c.9698G>A p.R3233H | Missense Mutation (SNP) | VAF 50/610 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV52816920; called by muse, mutect2
- PLXNB3 | c.5453G>A p.R1818H | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs1410439897; called by muse, mutect2, varscan2
- RAB9B | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs1321964920, COSV54588235; called by muse, mutect2
- RFC1 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs374549255, COSV62899615; called by muse, mutect2
- TP53 | c.596del p.G199Efs*48 | Frame Shift Del (DEL) | VAF 70/553 reads (13%) | catalogued as COSV52661319, COSV52679535, COSV53326529; called by mutect2, pindel, varscan2
- WDR81 | c.2981G>C p.R994P | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770995429; called by muse, mutect2
- ZNF831 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV64040627; called by muse, mutect2, varscan2
- ARHGAP11A | c.2022T>A p.F674L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MOB4 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- PAPOLA | c.1049A>C p.E350A | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- ZNF687 | c.3181G>T p.G1061W | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- AARS1 | c.2667C>T p.L889= | Silent (SNP) | VAF 51/618 reads (8%) | called by muse, mutect2
- ARMC3 | c.1308G>A p.Q436= | Silent (SNP) | VAF 45/538 reads (8%) | called by muse, mutect2
- FMR1 | c.1524C>T p.D508= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as rs376113075; called by muse, mutect2
- GIT1 | c.2175C>T p.G725= | Silent (SNP) | VAF 26/240 reads (11%) | catalogued as rs762322741; called by muse, mutect2, varscan2
- MARK4 | c.2250C>T p.L750= | Silent (SNP) | VAF 14/270 reads (5%) | catalogued as rs946478177; called by muse, mutect2
- MUC5B | c.12201C>T p.S4067= | Silent (SNP) | VAF 68/876 reads (8%) | called by muse, mutect2
- PCDHB16 | c.1665C>T p.N555= | Silent (SNP) | VAF 63/661 reads (10%) | catalogued as rs782078950, COSV53362553; called by muse, mutect2, varscan2
- TBC1D25 | c.1659C>T p.S553= | Silent (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- ZC3H11A | c.1140C>T p.L380= | Silent (SNP) | VAF 78/541 reads (14%) | called by muse, mutect2, varscan2
- ZC3H13 | c.21G>A p.K7= | Silent (SNP) | VAF 23/210 reads (11%) | catalogued as rs750929563; called by muse, mutect2, varscan2
- SYNE1 | c.16711-34C>T | Intron (SNP) | VAF 22/272 reads (8%) | catalogued as rs750991554; called by muse, mutect2
- TRIM59 | c.-86C>T | 5'UTR (SNP) | VAF 24/213 reads (11%) | catalogued as rs1394836351; called by muse, mutect2, varscan2
